Somatic mutation profile of tumor specimen TCGA-B7-5818-01A (aliquot TCGA-B7-5818-01A-11D-1600-08) from TCGA case TCGA-B7-5818, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.4 years (22,792 days).
Specimen TCGA-B7-5818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93066aad-b49e-4976-b2fc-304909b1857f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B7-5818-10A (Blood Derived Normal), aliquot TCGA-B7-5818-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc4a8ee2-f0a0-4d17-a5d8-0c8621122de3

The open-access MAF lists 413 somatic variants for this specimen: 309 protein-altering or splice-affecting, 98 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 277, Silent 98, Nonsense Mutation 15, Frame Shift Del 8, Frame Shift Ins 4, Intron 3, Splice Site 3, 3'Flank 2, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 74/179 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AC098582.1 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1486123639, COSV52024825; called by muse, mutect2, varscan2
- ACO1 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 95/208 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59385028; called by muse, mutect2, varscan2
- ACOX2 | c.1340T>G p.V447G | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV57150949; called by muse, mutect2, varscan2
- ACSM2A | c.1682C>A p.A561D (on ENST00000219054; = p.A482D on NM_001308169.2) | Missense Mutation (SNP) | VAF 120/341 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs1313776843, COSV54589939; called by muse, varscan2
- ADCY7 | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV54271077; called by muse, mutect2, varscan2
- ADGRV1 | c.16520C>T p.A5507V | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs1464093914, COSV67995678; called by muse, mutect2, varscan2
- ADNP2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as rs764899799, COSV51542449; called by muse, mutect2, varscan2
- AGMO | c.914G>A p.G305D | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV61124382; called by muse, mutect2, varscan2
- AHSG | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs755858937, COSV56609419; called by muse, mutect2, varscan2
- AIRE | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52397249; called by muse, mutect2, varscan2
- AKNAD1 | c.111A>C p.K37N | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV62203641; called by muse, mutect2, varscan2
- AL592490.1 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV69427921; called by muse, mutect2, varscan2
- ALOX5 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65554461; called by muse, mutect2, varscan2
- ANKRD1 | c.416T>A p.F139Y | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV63311217; called by muse, mutect2, varscan2
- ANKRD35 | c.2095A>G p.S699G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62911627; called by muse, mutect2, varscan2
- ANOS1 | c.616T>C p.S206P | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52926533; called by muse, mutect2, varscan2
- AP002512.3 | c.1173G>T p.M391I | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV54405369, COSV54408841; called by muse, mutect2, varscan2
- AQP12A | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs375647576; called by muse, mutect2, varscan2
- ARHGEF7 | c.1768C>T p.H590Y (on ENST00000375741 / NM_001113511.2; = p.H412Y on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54551941; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 63/95 reads (66%) | catalogued as rs758608743; called by mutect2, varscan2
- ARMC3 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs1021320309, COSV53067927; called by muse, mutect2, varscan2
- ARMH4 | c.1682T>G p.V561G | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV50774286; called by muse, mutect2, varscan2
- ASB14 | c.1021A>C p.N341H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67467732; called by muse, mutect2, varscan2
- ASCL1 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV57151459, COSV57152664; called by muse, mutect2, varscan2
- ATP8B1 | c.3304T>G p.S1102A | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52180351; called by muse, mutect2, varscan2
- ATXN3L | c.519A>C p.E173D | Missense Mutation (SNP) | VAF 65/90 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV66076258; called by muse, mutect2, varscan2
- B3GALNT1 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV57581242; called by muse, mutect2, varscan2
- BBS7 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 50/165 reads (30%) | catalogued as COSV52659595; called by muse, mutect2, varscan2
- BDP1 | c.2500C>A p.L834I | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV62434871; called by muse, mutect2, varscan2
- C3orf33 | c.796G>A p.E266K (on ENST00000340171 / NM_001308229.2; = p.E223K on NM_173657.2) | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs576856906, COSV60898407; called by muse, mutect2, varscan2
- CABIN1 | c.2645C>T p.T882M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs41310246; called by muse, mutect2, varscan2
- CADM2 | c.1064A>G p.D355G (on ENST00000407528 / NM_001167674.2; = p.D357G on NM_153184.4) | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs752725804, COSV67361428, COSV67405236; called by muse, mutect2, varscan2
- CAMK1G | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314268242, COSV50523270; called by muse, mutect2, varscan2
- CASR | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 51/327 reads (16%) | catalogued as COSV56141637; called by muse, mutect2, varscan2
- CBY2 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV60119882; called by muse, mutect2, varscan2
- CCDC102B | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0.235); catalogued as COSV60154738; called by muse, mutect2, varscan2
- CCDC191 | c.660A>C p.K220N | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV55676506; called by muse, mutect2, varscan2
- CCL20 | c.134T>G p.F45C | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as rs1221522990, COSV62591737; called by muse, mutect2, varscan2
- CD163L1 | c.1249T>C p.F417L | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV58024927; called by muse, mutect2
- CDH22 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs376968391; called by muse, mutect2, varscan2
- CDH7 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59881252; called by muse, mutect2, varscan2
- CDHR3 | c.67A>C p.I23L | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV58421877; called by muse, mutect2, varscan2
- CECR2 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52848430; called by muse, mutect2, varscan2
- CENPF | c.6951G>T p.Q2317H | Missense Mutation (SNP) | VAF 72/112 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV65279128; called by muse, mutect2, varscan2
- CEP170 | c.1522A>G p.N508D | Missense Mutation (SNP) | VAF 130/393 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV60514901; called by muse, mutect2, varscan2
- CES5A | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51870791; called by muse, mutect2, varscan2
- CFAP43 | c.3151A>C p.I1051L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV53381316; called by muse, mutect2, varscan2
- CFAP43 | c.2750A>G p.E917G | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53381323; called by muse, mutect2, varscan2
- CFAP65 | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs370056096; called by muse, mutect2, varscan2
- CFHR5 | c.653A>C p.E218A | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV56828522; called by muse, mutect2, varscan2
- CLCN2 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 130/208 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1173897230, COSV55600395; called by muse, mutect2, varscan2
- CLOCK | c.1588T>G p.L530V | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59404947; called by muse, mutect2, varscan2
- CMSS1 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV70441157; called by muse, mutect2, varscan2
- COG3 | c.655A>G p.S219G | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV63075317; called by muse, mutect2, varscan2
- COL11A1 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 56/197 reads (28%) | catalogued as COSV62187830, COSV99071323; called by muse, mutect2, varscan2
- COL24A1 | c.4031C>T p.P1344L | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV65311629, COSV65314409; called by muse, mutect2, varscan2
- COL6A6 | c.4843G>T p.G1615W | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV62038090; called by muse, mutect2, varscan2
- COL6A6 | c.5947G>A p.D1983N | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.997); catalogued as COSV62038106; called by muse, mutect2, varscan2
- COLEC10 | c.634A>T p.N212Y | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV60522931; called by muse, mutect2, varscan2
- CRHR2 | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59267929; called by muse, mutect2, varscan2
- CSDE1 | c.1504C>T p.Q502* (on ENST00000358528 / NM_001007553.3; = p.Q471* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 49/134 reads (37%) | catalogued as COSV54760369; called by muse, mutect2, varscan2
- CSMD1 | c.8458T>C p.Y2820H (on ENST00000520002; = p.Y2819H on NM_033225.6) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV59384524; called by muse, mutect2, varscan2
- CTNND2 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as COSV58929137; called by muse, mutect2, varscan2
- CYBRD1 | c.287T>G p.L96R | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58428396; called by muse, mutect2, varscan2
- DCTN6 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV55318689; called by muse, mutect2, varscan2
- DDHD1 | c.1303C>T p.R435C (on ENST00000323669; = p.R632C on NM_030637.3) | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs372260629; called by muse, mutect2, varscan2
- DDHD2 | c.532T>G p.S178A | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV68158818; called by muse, mutect2, varscan2
- DDX18 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.261); catalogued as COSV54309259; called by muse, mutect2, varscan2
- DENND2A | c.1187A>C p.K396T | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV52059226; called by muse, mutect2, varscan2
- DENND5A | c.2312G>A p.G771D | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60232183; called by muse, mutect2, varscan2
- DHRS7 | c.185T>G p.I62S | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53667639; called by muse, mutect2, varscan2
- DIRAS3 | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV63971232; called by muse, mutect2, varscan2
- DKK1 | c.552A>C p.Q184H | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.514); catalogued as COSV64760765; called by muse, mutect2, varscan2
- DLC1 | c.1548T>G p.I516M (on ENST00000276297 / NM_001348081.2; = p.I79M on NM_006094.5) | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52328430; called by muse, mutect2, varscan2
- DMGDH | c.1897G>T p.A633S | Missense Mutation (SNP) | VAF 141/476 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1462268145, COSV54869051; called by muse, mutect2, varscan2
- DNAH3 | c.3421C>T p.R1141W | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs371774380; called by muse, mutect2, varscan2
- DNAH5 | c.4560G>A p.M1520I | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV54252787, COSV99454047; called by muse, mutect2, varscan2
- DNAH6 | c.2167G>C p.V723L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1374037303, COSV99407868; called by muse, mutect2, varscan2
- DNPEP | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV56111987; called by muse, mutect2, varscan2
- DOCK10 | c.5821G>A p.D1941N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV51428071; called by muse, mutect2, varscan2
- DYNC2H1 | c.9538G>T p.D3180Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs776908424, COSV62107048; called by muse, mutect2, varscan2
- DZIP1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763110145, COSV61270277; called by muse, mutect2, varscan2
- EFCAB5 | c.2975G>C p.S992T | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs887403144, COSV57937778; called by muse, mutect2, varscan2
- EIF4G3 | c.3575A>C p.E1192A | Missense Mutation (SNP) | VAF 93/289 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV51694449; called by muse, mutect2, varscan2
- EME2 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369803881, COSV51603005; called by muse, varscan2
- EMSY | c.2006A>C p.K669T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV58266080; called by muse, mutect2
- EMSY | c.2468C>T p.S823L | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.236); catalogued as COSV58266086; called by muse, mutect2, varscan2
- ENOX2 | c.1334A>C p.E445A (on ENST00000338144 / NM_001382520.1; = p.E416A on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 260/359 reads (72%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.627); catalogued as COSV57658298; called by muse, mutect2, varscan2
- EPHA5 | c.394T>C p.F132L | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56674693, COSV99897673; called by muse, mutect2, varscan2
- EPHB3 | c.1622A>G p.E541G | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57809169; called by muse, mutect2, varscan2
- EPRS1 | c.3109A>T p.M1037L | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV65101612; called by muse, varscan2
- F13A1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs374508373, COSV53563807; called by muse, mutect2, varscan2
- FAM111B | c.2147A>G p.E716G | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV59113672; called by muse, mutect2, varscan2
- FAM171B | c.1112T>G p.F371C | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV59008841; called by muse, mutect2, varscan2
- FAM214B | c.843A>C p.K281N | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59717590; called by muse, mutect2, varscan2
- FAT1 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV71676074; called by muse, mutect2
- FCRL4 | c.1543A>G p.S515G | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.18); catalogued as COSV54866492, COSV54867547; called by muse, mutect2, varscan2
- FGF14 | c.560T>G p.V187G | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65958461; called by mutect2, varscan2
- FHL3 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65952868; called by muse, mutect2, varscan2
- FKBP8 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV55894193; called by muse, mutect2, varscan2
- FMO2 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV52950469; called by muse, mutect2, varscan2
- FMO5 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 145/479 reads (30%) | catalogued as COSV54210758; called by muse, mutect2, varscan2
- FOXE1 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1321530779, COSV64301047; called by muse, mutect2, varscan2
- FOXF1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52288020, COSV99296548; called by muse, mutect2, varscan2
- FZD1 | c.1305G>A p.W435* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as rs1563008191, COSV55313515; called by muse, mutect2, varscan2
- GART | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV63114704; called by muse, mutect2, varscan2
- GDPGP1 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV61576142; called by muse, mutect2, varscan2
- GLS2 | c.1287G>A p.M429I | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV57666073; called by muse, mutect2, varscan2
- GPR183 | c.182A>T p.K61I | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV63121734; called by muse, mutect2, varscan2
- GPRASP1 | c.1552T>G p.F518V | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV64356488; called by muse, mutect2, varscan2
- GRIK1 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV58732355, COSV58737056; called by muse, mutect2, varscan2
- GRIN2B | c.1459G>T p.G487W | Missense Mutation (SNP) | VAF 97/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74207966; called by muse, mutect2, varscan2
- GRM5 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs199784345, COSV59630521; called by muse, mutect2, varscan2
- GRM5 | c.1253T>C p.L418P | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1383111004, COSV59630541; called by muse, mutect2, varscan2
- GSAP | c.2366A>G p.K789R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs777710360, COSV57533254; called by muse, mutect2, varscan2
- GSDMC | c.943A>G p.N315D | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52699457; called by muse, mutect2, varscan2
- GSDMC | c.402A>C p.K134N | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.191); catalogued as COSV52699471; called by muse, mutect2, varscan2
- GUCY1A1 | c.1382A>C p.E461A | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.542); catalogued as COSV56656612; called by muse, mutect2, varscan2
- HDAC5 | c.2610C>T p.D870= | Splice Region (SNP) | VAF 16/89 reads (18%) | catalogued as COSV52243903; called by muse, mutect2, varscan2
- HECTD2 | c.507T>G p.F169L | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53224918; called by muse, mutect2, varscan2
- HERPUD2 | c.965T>G p.F322C | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60947450; called by muse, mutect2, varscan2
- HINT3 | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57650581; called by muse, mutect2
- HMCN1 | c.1996T>G p.L666V | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV54890844, COSV54942471; called by muse, mutect2, varscan2
- HORMAD1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59273296; called by muse, mutect2, varscan2
- HYDIN | c.13594G>A p.E4532K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101125133; called by muse, mutect2, varscan2
- ICAM5 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55749355; called by muse, mutect2, varscan2
- IFI16 | c.385A>G p.R129G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs777100386; called by muse, mutect2
- IFI16 | c.1970G>A p.R657Q (on ENST00000295809 / NM_001364867.2; = p.R601Q on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs766761172, COSV55540273; called by muse, mutect2, varscan2
- INTS6 | c.2639A>G p.Q880R | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.09); catalogued as COSV60880672; called by muse, mutect2, varscan2
- IQGAP1 | c.1583T>G p.V528G | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51591467; called by muse, mutect2, varscan2
- IRS4 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 129/179 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV64534143; called by muse, mutect2, varscan2
- KALRN | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as rs755363438, COSV53762509; called by muse, mutect2, varscan2
- KCNA4 | c.1543T>A p.F515I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60255996; called by muse, mutect2, varscan2
- KIF14 | c.3568A>T p.S1190C | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66264159; called by muse, mutect2, varscan2
- KIF17 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 68/93 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs777448525, COSV56122598; called by muse, mutect2, varscan2
- KIF27 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as COSV52831317; called by muse, mutect2, varscan2
- KIR3DL2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 134/444 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as rs1324180120; called by muse, mutect2
- KLHL1 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 162/319 reads (51%) | catalogued as rs1320029799, COSV64767628; called by muse, mutect2, varscan2
- KLHL40 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55137368; called by muse, mutect2, varscan2
- KRT6A | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs11266911, COSV58107944; called by muse, varscan2
- LAMA1 | c.2319G>T p.L773F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs781185458, COSV67544563; called by muse, mutect2, varscan2
- LCTL | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs1442865164, COSV57183189; called by muse, mutect2, varscan2
- LGSN | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs749286541, COSV65727549; called by muse, mutect2, varscan2
- LINGO2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV58064579; called by muse, mutect2, varscan2
- LIPG | c.1163A>T p.E388V | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54298288; called by muse, mutect2, varscan2
- LMBRD1 | c.1301T>G p.F434C (on ENST00000649011; = p.F412C on NM_018368.4) | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65300163; called by muse, mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 76/208 reads (37%) | catalogued as rs762083435; called by mutect2, varscan2
- LRRC52 | c.325A>C p.S109R | Missense Mutation (SNP) | VAF 135/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54233813; called by muse, mutect2, varscan2
- LRRC8C | c.878G>T p.C293F | Missense Mutation (SNP) | VAF 217/325 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65001378; called by muse, mutect2, varscan2
- LRRK2 | c.2787G>C p.L929F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.08); catalogued as COSV100110848; called by muse, mutect2, varscan2
- LRRK2 | c.2788C>T p.Q930* | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100110849; called by muse, mutect2, varscan2
- LYST | c.8828A>G p.Y2943C | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs1394283731, COSV67714271; called by muse, mutect2, varscan2
- MAGEA3 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 133/183 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64756546; called by muse, mutect2, varscan2
- MAN1B1 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65378803; called by muse, mutect2, varscan2
- MAP4K4 | c.2305G>A p.E769K (on ENST00000347699 / NM_001242559.2; = p.E687K on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV56340694; called by muse, mutect2, varscan2
- MARCHF10 | c.958G>T p.G320W | Missense Mutation (SNP) | VAF 388/770 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV60890510; called by muse, mutect2, varscan2
- MDC1 | c.5333T>G p.L1778R | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV64527729; called by muse, mutect2, varscan2
- MDGA1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as COSV51796194; called by muse, mutect2, varscan2
- MDH1 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV51865216; called by muse, mutect2, varscan2
- MED22 | c.428A>C p.E143A | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV59300103; called by muse, mutect2, varscan2
- MEIS3 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV58985187; called by muse, varscan2
- MGA | c.5027C>T p.P1676L | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54963162, COSV54964661, COSV99581021; called by muse, mutect2, varscan2
- MINK1 | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.995); catalogued as rs1247475016, COSV53420168; called by muse, mutect2, varscan2
- MNS1 | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.678); catalogued as COSV53070541, COSV99549911; called by muse, mutect2, varscan2
- MORC3 | c.2142A>C p.K714N | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV68689311; called by muse, mutect2
- MSRB1 | c.304A>C p.K102Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51908477; called by muse, mutect2, varscan2
- MTHFD1L | c.1912A>G p.K638E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV100945236; called by muse, mutect2, varscan2
- MUC16 | c.8861A>T p.Q2954L | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV67494928; called by muse, mutect2, varscan2
- MUC4 | c.1057T>G p.L353V | Missense Mutation (SNP) | VAF 117/600 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.374); catalogued as COSV62197277; called by muse, mutect2, varscan2
- MYBPC1 | c.761T>C p.F254S (on ENST00000550270 / NM_206820.2; = p.F279S on NM_002465.4) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62257687; called by muse, mutect2, varscan2
- MYH15 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as rs767277272, COSV56308500; called by muse, mutect2, varscan2
- MYO7B | c.5693T>G p.I1898R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV61444946; called by muse, mutect2, varscan2
- MYO9A | c.2798T>C p.L933P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61853377, COSV61857987; called by muse, mutect2, varscan2
- MYOM2 | c.4189C>T p.Q1397* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as COSV50775178; called by muse, mutect2, varscan2
- MZT1 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 92/445 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV64698271; called by muse, mutect2, varscan2
- NARS1 | c.1385T>G p.V462G | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56878209; called by muse, mutect2, varscan2
- NCOA6 | c.4559T>A p.V1520D | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV62868124; called by muse, mutect2, varscan2
- NDST4 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52137936; called by muse, mutect2, varscan2
- NELL2 | c.2066G>A p.C689Y | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61585769; called by muse, mutect2, varscan2
- NIPA1 | c.350A>T p.K117M | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV61680760, COSV61680894; called by muse, mutect2
- NIPSNAP3B | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as rs772780014, COSV66106940; called by muse, mutect2, varscan2
- NRP1 | c.139T>A p.S47T | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV55177716; called by muse, mutect2, varscan2
- NWD1 | c.3964G>A p.V1322I | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as rs141165642; called by muse, mutect2, varscan2
- OR2M7 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 169/494 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV58740776; called by muse, mutect2, varscan2
- OR4S2 | c.87T>G p.F29L | Missense Mutation (SNP) | VAF 100/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56748419; called by muse, mutect2, varscan2
- OR5M1 | c.663T>G p.I221M | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV73202431; called by muse, mutect2, varscan2
- OR8H3 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV100539199, COSV57911683; called by muse, mutect2, varscan2
- OSBPL6 | c.1541A>C p.D514A | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV51930779; called by muse, mutect2, varscan2
- OTULINL | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV57036537; called by muse, mutect2, varscan2
- P2RY1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV59310476; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.483T>G p.C161W (on ENST00000259318 / NM_001136562.3; = p.C392W on NM_007203.5) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.283); catalogued as COSV52181563; called by muse, mutect2, varscan2
- PARP14 | c.4726T>C p.Y1576H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71735610; called by muse, mutect2, varscan2
- PCDH15 | c.1080A>C p.K360N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV57308152, COSV57396278; called by muse, mutect2, varscan2
- PCDH17 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64976310; called by muse, mutect2, varscan2
- PCDHA1 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as COSV65373699; called by muse, mutect2, varscan2
- PCDHB7 | c.1559A>G p.D520G | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50817358; called by muse, mutect2, varscan2
- PCDHGA3 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.284); catalogued as COSV54035965; called by muse, mutect2, varscan2
- PCDHGB3 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs576893125, COSV54035982; called by muse, mutect2, varscan2
- PCLO | c.13858G>A p.D4620N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61667014; called by muse, mutect2, varscan2
- PCOLCE2 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV56002246; called by muse, mutect2, varscan2
- PGBD1 | c.1841T>A p.L614H | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52556145; called by muse, mutect2, varscan2
- PHLDB2 | c.382T>A p.F128I | Missense Mutation (SNP) | VAF 159/817 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as COSV67316199; called by muse, mutect2, varscan2
- PIGG | c.2833T>G p.L945V (on ENST00000453061 / NM_001127178.3; = p.L937V on NM_017733.4) | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56321533; called by muse, mutect2, varscan2
- PIWIL1 | c.1699A>G p.K567E | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.882); catalogued as COSV55352075; called by muse, mutect2, varscan2
- PLEKHG3 | c.1687G>A p.V563M (on ENST00000394691; = p.V619M on NM_001308147.2) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as rs1054527232, COSV55977986, COSV55983906; called by muse, mutect2, varscan2
- PNISR | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65080827; called by muse, mutect2, varscan2
- POLDIP2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV50228971; called by muse, mutect2, varscan2
- PRLR | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV51500801; called by muse, mutect2, varscan2
- PRRC2C | c.7556A>G p.Q2519R (on ENST00000367742; = p.Q2517R on NM_015172.4) | Missense Mutation (SNP) | VAF 84/367 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58913397; called by muse, mutect2, varscan2
- PTPN23 | c.4298A>T p.K1433M | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55545928, COSV55548482; called by muse, mutect2, varscan2
- PTPRJ | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as rs1285995741, COSV69250486; called by muse, mutect2, varscan2
- RASA3 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61873471; called by muse, mutect2, varscan2
- RBAK | c.1602A>T p.K534N | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs193921102, COSV62330968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBSN | c.1538A>C p.E513A | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV53795664; called by muse, mutect2, varscan2
- REEP3 | c.379A>T p.N127Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53427448; called by muse, mutect2, varscan2
- RELN | c.6595A>G p.S2199G | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59034084; called by muse, mutect2, varscan2
- RIBC2 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 57/125 reads (46%) | catalogued as COSV61582303; called by muse, mutect2, varscan2
- RIMS1 | c.2776T>C p.Y926H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV53485524; called by muse, mutect2, varscan2
- RNF148 | c.127A>C p.N43H | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57386568; called by muse, mutect2
- RNF213 | c.12752-1G>C p.X4251_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as COSV60409199; called by muse, mutect2, varscan2
- ROR1 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV64293369; called by muse, mutect2, varscan2
- RPA3 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs774710098, COSV56190099; called by muse, mutect2, varscan2
- RTTN | c.370T>C p.S124P | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as COSV55352237; called by muse, mutect2, varscan2
- RUFY3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV56917626; called by muse, mutect2, varscan2
- RXFP3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV57505431; called by muse, mutect2, varscan2
- SAMD9L | c.2207T>G p.I736S | Missense Mutation (SNP) | VAF 94/351 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV59085420; called by muse, mutect2, varscan2
- SEC23IP | c.1694T>A p.L565H | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64833103; called by muse, mutect2, varscan2
- SECISBP2L | c.1855T>A p.S619T (on ENST00000559471 / NM_001193489.2; = p.S574T on NM_014701.4) | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV55937948; called by muse, mutect2, varscan2
- SEPTIN4 | c.1162G>T p.G388* | Nonsense Mutation (SNP) | VAF 88/186 reads (47%) | catalogued as COSV58729081; called by muse, mutect2, varscan2
- SERPINF2 | c.368-2A>C p.X123_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV60664050, COSV60665815; called by muse, mutect2, varscan2
- SFXN4 | c.460A>C p.N154H | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57461101; called by muse, mutect2, varscan2
- SGCA | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1164863952, COSV56251117; called by muse, mutect2, varscan2
- SIAH2 | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100469227, COSV57262938; called by muse, mutect2, varscan2
- SIX6 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59801879, COSV59803007; called by muse, mutect2, varscan2
- SLC17A6 | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.391); catalogued as COSV54141515; called by muse, mutect2, varscan2
- SLC22A16 | c.311A>C p.N104T | Missense Mutation (SNP) | VAF 91/335 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57926827, COSV57934838; called by muse, mutect2, varscan2
- SLC25A31 | c.918A>C p.E306D | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55421981; called by muse, mutect2, varscan2
- SLC25A42 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs752073615; called by muse, mutect2
- SLC2A9 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV53329014; called by muse, mutect2, varscan2
- SLC35G3 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52012814; called by muse, mutect2, varscan2
- SLC9B2 | c.70T>G p.S24A | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60022494; called by muse, mutect2, varscan2
- SLCO4C1 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60520364; called by muse, mutect2, varscan2
- SLITRK4 | c.1618G>T p.V540L | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV62026650; called by muse, mutect2
- SLMAP | c.1716A>C p.E572D (on ENST00000428312 / NM_001377924.1; = p.E634D on NM_007159.5) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.995); catalogued as COSV55853899; called by muse, mutect2, varscan2
- SMG1 | c.8674G>C p.E2892Q | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.478); catalogued as COSV67174871; called by muse, mutect2, varscan2
- SNRPN | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs775190561, COSV57594364, COSV57599888; called by muse, mutect2, varscan2
- SP100 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV51009970; called by muse, mutect2, varscan2
- SP140 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as COSV59455227; called by muse, mutect2, varscan2
- SPATS1 | c.147T>G p.N49K | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55825036; called by muse, mutect2, varscan2
- SPRED2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV62695921; called by muse, mutect2, varscan2
- ST18 | c.2871G>A p.M957I | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV52509988; called by muse, mutect2, varscan2
- SUV39H2 | c.991C>T p.H331Y (on ENST00000354919 / NM_001193424.2; = p.H271Y on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57955593; called by muse, mutect2, varscan2
- SYCP2L | c.798T>G p.I266M | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV51657620; called by muse, mutect2, varscan2
- SYT2 | c.344A>C p.Q115P | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.142); catalogued as COSV66143273; called by muse, mutect2, varscan2
- TAF1L | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54270405; called by muse, mutect2, varscan2
- TANC1 | c.5020A>C p.K1674Q | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.518); catalogued as COSV55097318; called by muse, mutect2
- TBC1D8 | c.2636T>C p.I879T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV65216752; called by muse, mutect2, varscan2
- TCHH | c.419A>C p.K140T | Missense Mutation (SNP) | VAF 148/432 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); catalogued as rs770478540, COSV64277836; called by muse, mutect2, varscan2
- TDRD6 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV60174750; called by muse, mutect2, varscan2
- TDRD6 | c.2515A>G p.S839G | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV60178767; called by muse, mutect2, varscan2
- TMEM132D | c.3103C>T p.P1035S | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV67160894, COSV67162433; called by muse, mutect2, varscan2
- TNIK | c.3974A>C p.K1325T | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52696524; called by muse, mutect2, varscan2
- TOX2 | c.168C>G p.N56K (on ENST00000358131 / NM_001098798.2; = p.N5K on NM_032883.3) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV57895891; called by muse, mutect2, varscan2
- TRANK1 | c.4873T>C p.S1625P | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1228384923, COSV57164436; called by muse, mutect2, varscan2
- TRIM54 | c.403A>G p.N135D | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV56085620; called by muse, mutect2, varscan2
- TRMT10C | c.1064A>G p.Q355R | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59306973; called by muse, mutect2, varscan2
- TSBP1 | c.1000A>C p.K334Q (on ENST00000617061; = p.K339Q on NM_006781.5) | Missense Mutation (SNP) | VAF 94/317 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV66660887; called by muse, mutect2, varscan2
- TTC14 | c.2286A>C p.K762N | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as rs1163198239, COSV56013974, COSV56014249; called by muse, mutect2, varscan2
- TTLL3 | c.2648A>T p.K883M | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV59615874; called by muse, mutect2, varscan2
- UBQLN3 | c.827A>C p.N276T | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV61165873; called by muse, varscan2
- USH2A | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56438690; called by muse, mutect2, varscan2
- USP29 | c.2708C>T p.T903I | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV54146772; called by muse, varscan2
- USP36 | c.3123A>G p.K1041= | Splice Region (SNP) | VAF 62/130 reads (48%) | catalogued as COSV61754638; called by muse, mutect2, varscan2
- VIRMA | c.2688A>C p.E896D | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); catalogued as COSV52591454; called by muse, mutect2, varscan2
- VPS13D | c.2750T>G p.I917S | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.373); catalogued as COSV50687075; called by muse, mutect2, varscan2
- VXN | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV59686289; called by muse, mutect2, varscan2
- WAPL | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV53940322; called by muse, mutect2, varscan2
- WASHC4 | c.2204A>G p.K735R | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV59892426; called by muse, mutect2, varscan2
- WDR53 | c.770T>G p.L257R | Missense Mutation (SNP) | VAF 72/408 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV60285007; called by muse, mutect2, varscan2
- WDR5B | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58072373, COSV58073141; called by muse, mutect2, varscan2
- WNK1 | c.3610C>T p.Q1204* (on ENST00000315939 / NM_018979.4; = p.Q957* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 50/154 reads (32%) | catalogued as COSV60045617; called by muse, mutect2, varscan2
- YTHDC2 | c.3416G>A p.R1139K | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV50739115, COSV50744289; called by muse, mutect2, varscan2
- ZBBX | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV56801733; called by muse, mutect2, varscan2
- ZMIZ2 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54811072; called by muse, mutect2, varscan2
- ZNF148 | c.1414A>G p.K472E | Missense Mutation (SNP) | VAF 81/412 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62307767; called by muse, mutect2, varscan2
- ZNF175 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV51798514; called by muse, mutect2, varscan2
- ZNF282 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV50484126; called by muse, mutect2, varscan2
- ZNF439 | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV58311169; called by muse, mutect2, varscan2
- ZNF518A | c.2465G>A p.R822K | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV60153476; called by muse, mutect2, varscan2
- ZNF528 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs199532990, COSV64621318; called by muse, mutect2, varscan2
- ZNF639 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs1481466802, COSV58384705; called by muse, mutect2, varscan2
- ZNF721 | c.2630G>A p.G877E (on ENST00000338977; = p.G889E on NM_133474.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59090876, COSV59097300; called by muse, mutect2, varscan2
- ZSCAN2 | c.1181A>C p.D394A | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV57572724; called by muse, mutect2, varscan2
- ZSWIM2 | c.803T>G p.L268R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as COSV54579697; called by muse, mutect2
- COL12A1 | c.6879del p.K2293Nfs*35 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- EEF1G | c.974_975del p.E325Vfs*5 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by pindel, varscan2
- KANSL1L | c.1774del p.T592Qfs*4 | Frame Shift Del (DEL) | VAF 58/166 reads (35%) | called by mutect2, pindel, varscan2
- PPP1R3C | c.905del p.P302Qfs*35 | Frame Shift Del (DEL) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- RBM47 | c.374dup p.R126Afs*5 | Frame Shift Ins (INS) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- RCC1L | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RNASEL | c.2053del p.I685Lfs*16 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | called by mutect2, pindel, varscan2
- ROCK2 | c.3028_3031del p.E1010* | Frame Shift Del (DEL) | VAF 50/178 reads (28%) | called by mutect2, pindel, varscan2
- SLC24A3 | c.508_508+8dup | Nonsense Mutation (INS) | VAF 24/80 reads (30%) | called by mutect2, varscan2
- SLC8B1 | c.234_237dup p.Y80Gfs*75 | Frame Shift Ins (INS) | VAF 32/196 reads (16%) | called by pindel, varscan2
- ST6GALNAC3 | c.425del p.Y142Ffs*20 | Frame Shift Del (DEL) | VAF 39/199 reads (20%) | called by mutect2, pindel, varscan2
- TDRD1 | c.315dup p.L106Ifs*13 | Frame Shift Ins (INS) | VAF 37/139 reads (27%) | called by mutect2, pindel, varscan2
- TPTE | c.556A>C p.N186H (on ENST00000618007 / NM_199261.4; = p.N168H on NM_199259.4) | Missense Mutation (SNP) | VAF 51/410 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ACIN1 | c.498A>C p.S166= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs762302314, COSV52982284; called by muse, mutect2, varscan2
- ACSM2A | c.525T>G p.P175= (on ENST00000219054; = p.P96= on NM_001308169.2) | Silent (SNP) | VAF 100/412 reads (24%) | catalogued as COSV54588702; called by muse, mutect2, varscan2
- ADAMTS6 | c.2349T>C p.A783= | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as rs963377230, COSV66864955; called by muse, mutect2, varscan2
- ADGRA1 | c.1617G>A p.L539= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV66927481; called by muse, mutect2, varscan2
- AOAH | c.1182C>T p.S394= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV51750762; called by muse, mutect2, varscan2
- ASAP2 | c.1539C>T p.P513= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV55638887; called by muse, mutect2, varscan2
- ASB7 | c.639C>T p.D213= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs757982775, COSV58404626; called by muse, mutect2, varscan2
- ASNSD1 | c.1341C>T p.H447= | Silent (SNP) | VAF 92/281 reads (33%) | catalogued as rs750043361, COSV53624938; called by muse, mutect2, varscan2
- ATG2B | c.1221C>T p.F407= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as COSV63425684; called by muse, mutect2, varscan2
- BORCS5 | c.66T>G p.P22= | Silent (SNP) | VAF 82/203 reads (40%) | catalogued as COSV53805086; called by muse, mutect2, varscan2
- CARNMT1 | c.1143T>C p.S381= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as COSV65194909; called by muse, mutect2, varscan2
- CCL15 | c.303T>G p.V101= | Silent (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- CD247 | c.309G>A p.R103= (on ENST00000362089 / NM_198053.3; = p.R102= on NM_000734.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV62980364; called by muse, mutect2, varscan2
- CDC42BPG | c.690G>A p.V230= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as COSV61349286; called by muse, mutect2, varscan2
- CDHR3 | c.2592C>T p.G864= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV58421900; called by muse, mutect2, varscan2
- CDK20 | c.18C>T p.I6= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV57484389; called by muse, mutect2, varscan2
- CEMIP | c.3972C>T p.F1324= | Silent (SNP) | VAF 72/195 reads (37%) | catalogued as rs754943195, COSV54996491; called by muse, mutect2, varscan2
- CHDH | c.1515A>G p.K505= | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as COSV55465333; called by muse, mutect2, varscan2
- CLOCK | c.1024C>T p.L342= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV59404955; called by muse, mutect2, varscan2
- CPAMD8 | c.3669C>T p.T1223= (on ENST00000651564; = p.T1176= on NM_015692.5) | Silent (SNP) | VAF 68/171 reads (40%) | catalogued as COSV71597404; called by muse, mutect2, varscan2
- DAG1 | c.2187A>G p.S729= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV58187254; called by muse, mutect2, varscan2
- DENND5A | c.3138G>A p.R1046= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV60237976; called by muse, mutect2, varscan2
- DLG2 | c.537G>A p.L179= | Silent (SNP) | VAF 58/175 reads (33%) | catalogued as COSV54686508; called by muse, mutect2, varscan2
- DNAH8 | c.9054C>T p.D3018= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs1179971588, COSV59481074; called by muse, mutect2, varscan2
- DNAH8 | c.11268C>T p.H3756= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as COSV59481087; called by muse, mutect2, varscan2
- DNMT1 | c.3739C>T p.L1247= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV61583001, COSV61583985; called by muse, mutect2, varscan2
- DYRK1B | c.594C>T p.Y198= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs372504975; called by muse, mutect2, varscan2
- ERCC6L2 | c.1638G>A p.A546= | Silent (SNP) | VAF 80/225 reads (36%) | catalogued as rs376256925, COSV56634294; called by muse, mutect2, varscan2
- FAM83D | c.1749C>T p.S583= | Silent (SNP) | VAF 95/305 reads (31%) | catalogued as COSV54159254; called by muse, mutect2, varscan2
- FAT2 | c.10659C>T p.I3553= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs374245805; called by muse, mutect2, varscan2
- FLNC | c.45C>T p.G15= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV57954616; called by muse, mutect2, varscan2
- FMNL2 | c.1485A>C p.P495= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV56504761; called by muse, mutect2, varscan2
- GLIPR1L2 | c.597G>A p.T199= | Silent (SNP) | VAF 100/304 reads (33%) | catalogued as rs776067780, COSV100248434, COSV57556313; called by muse, mutect2, varscan2
- GPAT2 | c.1647C>A p.V549= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV64003966; called by muse, mutect2, varscan2
- GRIN2B | c.3751C>T p.L1251= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs200186058, COSV74207964; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM2 | c.2613G>A p.S871= | Silent (SNP) | VAF 106/287 reads (37%) | catalogued as rs775686792, COSV56587188; called by muse, mutect2, varscan2
- GSTM2 | c.84C>T p.Y28= | Silent (SNP) | VAF 55/166 reads (33%) | catalogued as rs1369888752, COSV53984082; called by muse, mutect2, varscan2
- GTF2F1 | c.336C>T p.G112= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs200049909, COSV66727082; called by muse, mutect2, varscan2
- GZF1 | c.1887T>C p.Y629= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV57638378; called by muse, mutect2, varscan2
- HAUS3 | c.954C>T p.T318= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as COSV54723858, COSV71319287; called by muse, mutect2, varscan2
- HEXB | c.714A>T p.I238= | Silent (SNP) | VAF 45/149 reads (30%) | catalogued as COSV54670075; called by muse, mutect2, varscan2
- HLA-DOA | c.684C>T p.G228= | Silent (SNP) | VAF 54/168 reads (32%) | catalogued as COSV57715607; called by muse, mutect2, varscan2
- HOXA6 | c.369C>T p.L123= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as COSV56071999; called by muse, mutect2, varscan2
- KCNA1 | c.267C>T p.F89= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs371963908; called by muse, mutect2, varscan2
- KLHL28 | c.306G>A p.Q102= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as COSV100753044, COSV61889402; called by muse, mutect2, varscan2
- LRP2 | c.5482T>C p.L1828= | Silent (SNP) | VAF 56/138 reads (41%) | catalogued as COSV55574930; called by muse, mutect2, varscan2
- LY9 | c.1575C>T p.A525= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV54438082; called by muse, mutect2, varscan2
- MAGEA4 | c.303C>T p.D101= | Silent (SNP) | VAF 84/119 reads (71%) | catalogued as rs1444291172, COSV52341370; called by muse, mutect2, varscan2
- MAP3K9 | c.1155C>T p.C385= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV67122909; called by muse, mutect2, varscan2
- MPV17 | c.450C>T p.P150= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1244633595, COSV51990447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRGPRX3 | c.159C>A p.G53= | Silent (SNP) | VAF 60/211 reads (28%) | catalogued as COSV66934837; called by muse, mutect2, varscan2
- MS4A12 | c.801A>G p.K267= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV50015745; called by muse, mutect2, varscan2
- MUC4 | c.13044C>T p.F4348= (on ENST00000463781 / NM_018406.7; = p.F112= on NM_004532.6) | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV57803569; called by muse, mutect2, varscan2
- MYCBP2 | c.5619T>A p.S1873= (on ENST00000357337; = p.S1911= on NM_015057.5) | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs766498773, COSV62039518; called by muse, mutect2, varscan2
- NAV2 | c.4851G>A p.K1617= (on ENST00000396087 / NM_001244963.2; = p.K1594= on NM_145117.5) | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV60665494; called by muse, mutect2, varscan2
- NLRP4 | c.882A>G p.S294= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as rs201335042, COSV56723559; called by muse, mutect2, varscan2
- NLRP5 | c.1371G>A p.A457= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs370683647; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUBPL | c.804T>G p.L268= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV55275825; called by muse, mutect2, varscan2
- OBSCN | c.22914C>T p.S7638= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV63489167; called by muse, mutect2, varscan2
- OR2AT4 | c.354C>T p.F118= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV59407632; called by muse, mutect2, varscan2
- OR2Y1 | c.495C>T p.A165= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV57136780, COSV57137976; called by muse, mutect2, varscan2
- OR4C12 | c.720T>C p.S240= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV100078790, COSV58861140; called by muse, mutect2, varscan2
- OR6C74 | c.393C>A p.T131= | Silent (SNP) | VAF 85/267 reads (32%) | catalogued as COSV59606795, COSV59607370; called by muse, mutect2, varscan2
- OR8H1 | c.151C>T p.L51= | Silent (SNP) | VAF 166/532 reads (31%) | catalogued as COSV57295995; called by muse, mutect2, varscan2
- PAN3 | c.2517T>A p.L839= | Silent (SNP) | VAF 47/182 reads (26%) | catalogued as COSV56707498; called by muse, mutect2, varscan2
- PASK | c.2613C>T p.V871= | Silent (SNP) | VAF 49/152 reads (32%) | catalogued as COSV52160701; called by muse, mutect2, varscan2
- PCNX3 | c.1953C>T p.A651= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2
- PNLIPRP2 | c.858C>T p.F286= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs782563884, COSV53944608; called by muse, mutect2, varscan2
- POLQ | c.1875A>G p.P625= | Silent (SNP) | VAF 61/289 reads (21%) | catalogued as COSV51761676; called by muse, mutect2, varscan2
- POSTN | c.1563G>A p.L521= | Silent (SNP) | VAF 50/254 reads (20%) | catalogued as COSV65713939, COSV65714714; called by muse, mutect2, varscan2
- PPARGC1A | c.1440G>A p.K480= | Silent (SNP) | VAF 55/218 reads (25%) | catalogued as rs1265026069, COSV53533768; called by muse, mutect2, varscan2
- PPFIA4 | c.3381G>A p.P1127= (on ENST00000447715; = p.P1128= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- PROS1 | c.420T>C p.S140= | Silent (SNP) | VAF 106/470 reads (23%) | catalogued as COSV62399728; called by muse, mutect2, varscan2
- PTPRM | c.1527A>G p.T509= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as rs377642289; called by muse, mutect2, varscan2
- RAC1 | c.543C>T p.P181= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs144238799; called by muse, mutect2, varscan2
- ROBO2 | c.183C>A p.T61= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV59939593; called by muse, mutect2, varscan2
- ROCK1 | c.2445G>A p.L815= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV67699456; called by muse, mutect2, varscan2
- RSPH10B2 | c.444G>A p.T148= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs759536851, COSV99786277; called by mutect2, varscan2
- RUSC1 | c.2424T>C p.S808= (on ENST00000368352 / NM_001105203.2; = p.S339= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 151/445 reads (34%) | catalogued as COSV52742809; called by muse, mutect2, varscan2
- RYR3 | c.9621C>T p.P3207= (on ENST00000389232; = p.P3208= on NM_001036.6) | Silent (SNP) | VAF 51/159 reads (32%) | catalogued as rs569095648, COSV66808901; called by muse, mutect2, varscan2
- SCG2 | c.228A>G p.P76= | Silent (SNP) | VAF 72/219 reads (33%) | catalogued as rs201723907, COSV59541886; called by muse, mutect2, varscan2
- SFSWAP | c.1305C>G p.S435= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV55525999; called by muse, mutect2, varscan2
- SHOX2 | c.912A>G p.A304= (on ENST00000441443 / NM_006884.3; = p.A328= on NM_003030.4) | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as COSV101273811; called by muse, mutect2, varscan2
- SLC35B1 | c.228G>A p.K76= (on ENST00000649906; = p.K39= on NM_005827.4) | Silent (SNP) | VAF 116/246 reads (47%) | catalogued as rs1326409399, COSV53604291; called by muse, varscan2
- SNRK | c.930A>G p.R310= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV56070978; called by muse, mutect2, varscan2
- SPDYA | c.162C>T p.N54= | Silent (SNP) | VAF 91/237 reads (38%) | catalogued as COSV61857494; called by muse, mutect2, varscan2
- SPHKAP | c.1356T>C p.V452= | Silent (SNP) | VAF 58/181 reads (32%) | catalogued as COSV60894676; called by muse, mutect2, varscan2
- ST7 | c.390C>T p.V130= | Silent (SNP) | VAF 45/207 reads (22%) | catalogued as COSV55393023; called by muse, mutect2, varscan2
- SYNE2 | c.54C>T p.I18= | Silent (SNP) | VAF 46/178 reads (26%) | catalogued as rs372179532; called by muse, mutect2, varscan2
- TH | c.1302G>A p.L434= (on ENST00000381178 / NM_199292.3; = p.L403= on NM_000360.4) | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as rs1255096793, COSV51748488; called by muse, mutect2, varscan2
- TLR9 | c.2949G>T p.L983= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV62347407, COSV62348518; called by muse, mutect2, varscan2
- TMEM37 | c.417C>T p.S139= | Silent (SNP) | VAF 135/398 reads (34%) | catalogued as rs148949485; called by muse, mutect2, varscan2
- TRANK1 | c.2997C>T p.D999= | Silent (SNP) | VAF 63/269 reads (23%) | catalogued as COSV57164457; called by muse, mutect2, varscan2
- TTN | c.384T>C p.T128= | Silent (SNP) | VAF 64/214 reads (30%) | catalogued as COSV60355154; called by muse, mutect2, varscan2
- UBE2R2 | c.324A>G p.E108= | Silent (SNP) | VAF 76/201 reads (38%) | catalogued as rs772728061, COSV54292996; called by muse, mutect2, varscan2
- USH1C | c.714C>T p.I238= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV50037153; called by muse, mutect2
- VTI1B | c.495A>G p.E165= | Silent (SNP) | VAF 92/271 reads (34%) | catalogued as COSV53620843; called by muse, mutect2, varscan2
- ZBTB48 | c.981T>C p.C327= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV59840842; called by muse, mutect2, varscan2
- ACTRT3 | chr3:169765022 A>T | 3'Flank (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2494G>A | Intron (SNP) | VAF 46/140 reads (33%) | catalogued as COSV57933945; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397720 G>A | 3'Flank (SNP) | VAF 58/160 reads (36%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-48037T>A | Intron (SNP) | VAF 30/82 reads (37%) | catalogued as COSV67450281; called by muse, mutect2, varscan2
- SPTBN4 | c.5915+66C>T | Intron (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100151623; called by muse, mutect2, varscan2
- ZNF99 | c.*1072C>A | 3'UTR (SNP) | VAF 46/78 reads (59%) | catalogued as COSV68056811; called by muse, mutect2, varscan2
